Somatic mutation profile of tumor specimen C3N-02332-01 (aliquot CPT0135740009) from CPTAC case C3N-02332, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 66.1 years (24,138 days).
Specimen C3N-02332-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58902a78-9ce6-4b5b-b251-aaecd2b907b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02332-71 (Blood Derived Normal), aliquot CPT0135860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0536efd3-2938-49de-866a-f59c92c6507d

The open-access MAF lists 69 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Frame Shift Del 10, Intron 3, Splice Site 3, Nonsense Mutation 2, Frame Shift Ins 2, 3'UTR 2, In Frame Del 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.2187del p.P730Lfs*2 | Frame Shift Del (DEL) | VAF 33/268 reads (12%) | catalogued as COSV51649623; called by mutect2, pindel, varscan2
- GALNT5 | c.2731G>A p.G911R | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV52035831; called by muse, mutect2, varscan2
- GCGR | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as rs758161776; called by muse, mutect2, varscan2
- GRIN3A | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1190925199; called by muse, mutect2, varscan2
- HERC1 | c.1636G>T p.G546C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101496726; called by muse, mutect2, varscan2
- INTS12 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs62320294; called by muse, mutect2, varscan2
- NEB | c.3271G>C p.D1091H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99423696; called by muse, varscan2
- NRK | c.4183C>T p.L1395F | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs745850463; called by muse, mutect2, varscan2
- SYNE2 | c.19141C>T p.R6381W | Missense Mutation (SNP) | VAF 72/536 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs372959292; called by muse, mutect2, varscan2
- TRIM33 | c.2579G>T p.G860V | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61820858; called by muse, mutect2
- VHL | c.550del p.L184Sfs*18 | Frame Shift Del (DEL) | VAF 78/460 reads (17%) | catalogued as COSV56568399; called by mutect2, pindel, varscan2
- ZNF721 | c.2152C>T p.R718C (on ENST00000338977; = p.R730C on NM_133474.4) | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782608224, COSV59097456; called by muse, mutect2, varscan2
- ACAA2 | c.580A>G p.N194D | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by mutect2, varscan2
- ALDH7A1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 73/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD44 | c.2230G>C p.A744P | Missense Mutation (SNP) | VAF 72/409 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATP12A | c.2781del p.E927Dfs*3 | Frame Shift Del (DEL) | VAF 42/240 reads (18%) | called by mutect2, pindel, varscan2
- BLNK | c.1200del p.F400Lfs*50 | Frame Shift Del (DEL) | VAF 31/187 reads (17%) | called by mutect2, pindel, varscan2
- CC2D1A | c.405del p.L136Wfs*62 | Frame Shift Del (DEL) | VAF 19/102 reads (19%) | called by mutect2, pindel, varscan2
- CC2D2A | c.78A>T p.R26S | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD1D | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- CEP192 | c.4109G>C p.G1370A | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CNIH1 | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); called by muse, mutect2
- EIF2B2 | c.486T>G p.N162K | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM50A | c.1011+1del | Frame Shift Del (DEL) | VAF 42/208 reads (20%) | called by mutect2, pindel, varscan2
- GRHL3 | c.1206G>C p.K402N (on ENST00000350501 / NM_198174.3; = p.K407N on NM_021180.3) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2
- IDUA | c.1117A>G p.N373D | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IFIH1 | c.1136C>A p.P379Q | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KCNJ15 | c.592_596del p.Q198Sfs*45 | Frame Shift Del (DEL) | VAF 31/228 reads (14%) | called by mutect2, pindel, varscan2
- KNL1 | c.909del p.D304Mfs*4 (on ENST00000346991 / NM_170589.5; = p.D278Mfs*4 on NM_144508.5) | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- LMOD3 | c.1649T>G p.L550R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LPAR1 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- METTL3 | c.1518+2T>A p.X506_splice | Splice Site (SNP) | VAF 55/348 reads (16%) | called by muse, mutect2, varscan2
- MS4A18 | c.739-1G>C p.X247_splice (on ENST00000398983; = p.X249_splice on NM_001354471.1) | Splice Site (SNP) | VAF 57/225 reads (25%) | called by muse, mutect2, varscan2
- ODF3B | c.540+1del p.X180_splice | Splice Site (DEL) | VAF 60/352 reads (17%) | called by mutect2, pindel, varscan2
- OR2L2 | c.126del p.S43Pfs*2 | Frame Shift Del (DEL) | VAF 24/206 reads (12%) | called by mutect2, varscan2
- P2RY1 | c.718dup p.I240Nfs*50 | Frame Shift Ins (INS) | VAF 29/203 reads (14%) | called by mutect2, pindel, varscan2
- PEX10 | c.121A>T p.K41* | Nonsense Mutation (SNP) | VAF 50/411 reads (12%) | called by muse, mutect2
- PEX10 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PHF3 | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRLR | c.900C>G p.D300E | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PSMD2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RIMS3 | c.644del p.K215Rfs*25 | Frame Shift Del (DEL) | VAF 71/398 reads (18%) | called by mutect2, pindel, varscan2
- SRCAP | c.7568C>T p.P2523L | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- STAP2 | c.161dup p.N54Kfs*16 | Frame Shift Ins (INS) | VAF 20/129 reads (16%) | called by mutect2, pindel, varscan2
- SYNE1 | c.6721G>C p.E2241Q (on ENST00000367255 / NM_182961.4; = p.E2248Q on NM_033071.3) | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBCCD1 | c.1380_1382dup p.L460_L461insF | In Frame Ins (INS) | VAF 74/473 reads (16%) | called by mutect2, pindel, varscan2
- TEX55 | c.1064A>T p.N355I | Missense Mutation (SNP) | VAF 57/281 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TNFSF10 | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- USP32 | c.3626A>C p.Q1209P | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZBTB41 | c.2224_2226del p.H742del | In Frame Del (DEL) | VAF 78/429 reads (18%) | called by mutect2, pindel, varscan2
- ZNF276 | c.1579G>C p.E527Q (on ENST00000443381 / NM_001113525.2; = p.E452Q on NM_152287.4) | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- B4GALNT3 | c.2160G>A p.Q720= | Silent (SNP) | VAF 68/406 reads (17%) | called by muse, mutect2, varscan2
- BID | c.204T>C p.F68= (on ENST00000317361 / NM_197966.2; = p.F22= on NM_001196.4) | Silent (SNP) | VAF 58/367 reads (16%) | called by muse, mutect2, varscan2
- C1R | c.576A>C p.P192= (on ENST00000536053 / NM_001354346.2; = p.P178= on NM_001733.7) | Silent (SNP) | VAF 41/297 reads (14%) | called by muse, mutect2, varscan2
- C20orf27 | c.106C>T p.L36= (on ENST00000379772 / NM_001258429.2; = p.L61= on NM_001039140.3) | Silent (SNP) | VAF 42/294 reads (14%) | called by muse, mutect2, varscan2
- COPB1 | c.2310A>G p.E770= | Silent (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- EXTL1 | c.1143A>G p.S381= | Silent (SNP) | VAF 62/352 reads (18%) | called by muse, mutect2, varscan2
- HNF4G | c.330T>C p.A110= (on ENST00000354370 / NM_001330561.2; = p.A157= on NM_004133.5) | Silent (SNP) | VAF 37/212 reads (17%) | called by muse, mutect2, varscan2
- KIAA0513 | c.636C>T p.Y212= | Silent (SNP) | VAF 53/396 reads (13%) | catalogued as rs757841670, COSV50741326; called by muse, mutect2, varscan2
- MSLN | c.45C>T p.T15= | Silent (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- RBM28 | c.312T>A p.A104= | Silent (SNP) | VAF 47/254 reads (19%) | called by muse, mutect2, varscan2
- SOGA3 | c.2625C>T p.N875= | Silent (SNP) | VAF 65/425 reads (15%) | catalogued as rs1344194630; called by muse, mutect2, varscan2
- SULF1 | c.2397G>A p.E799= | Silent (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.-123T>C | 5'UTR (SNP) | VAF 37/314 reads (12%) | called by muse, mutect2, varscan2
- CDKL1 | c.172-3157C>A | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, varscan2
- CDKL5 | c.555-37T>G | Intron (SNP) | VAF 35/175 reads (20%) | called by muse, mutect2, varscan2
- CYP21A2 | c.1119-34del | Intron (DEL) | VAF 87/796 reads (11%) | called by mutect2, pindel, varscan2
- PYCR1 | c.*40_*41insTTTT | 3'UTR (INS) | VAF 37/185 reads (20%) | called by mutect2, pindel, varscan2
- SERPINF2 | c.*43del | 3'UTR (DEL) | VAF 22/97 reads (23%) | called by mutect2, pindel, varscan2
